Somatic mutation profile of tumor specimen ALCH-AE2R-TTP1-A (aliquot ALCH-AE2R-TTP1-A-3-0-D-A618-36) from ALCHEMIST case ALCH-AE2R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Acinar adenocarcinoma; Age at diagnosis: 63.9 years (23,333 days).
Specimen ALCH-AE2R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3ab6971-8520-4936-902d-0683acecc925.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE2R-NB1-A (Blood Derived Normal), aliquot ALCH-AE2R-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14d3300e-5bc2-4f6c-b0f0-0d3bfccb184a

The open-access MAF lists 42 somatic variants for this specimen: 34 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 4, Nonsense Mutation 3, Intron 2, 3'UTR 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>C p.D488H | Missense Mutation (SNP) | VAF 105/400 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- DDX41 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs747842313; called by muse, mutect2, varscan2
- EPHA6 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761842720; called by mutect2, varscan2
- FARS2 | c.848G>C p.G283A | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV51164425; called by muse, mutect2, varscan2
- HEPACAM2 | c.337C>T p.Q113* (on ENST00000394468 / NM_001039372.4; = p.Q101* on NM_198151.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/259 reads (11%) | catalogued as rs1466486228; called by muse, mutect2, varscan2
- ING5 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1559314523, COSV57979934; called by muse, mutect2, varscan2
- KIDINS220 | c.5206C>T p.R1736* | Nonsense Mutation (SNP) | VAF 66/538 reads (12%) | catalogued as rs755413482; called by muse, mutect2, varscan2
- LOXL3 | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200579857; called by muse, mutect2, varscan2
- MAP2 | c.4835G>A p.R1612H | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs571439742; called by muse, mutect2, varscan2
- NIF3L1 | c.1069C>T p.H357Y (on ENST00000409020 / NM_001369444.1; = p.H330Y on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/545 reads (4%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.788); catalogued as rs1441144897; called by muse, mutect2
- PRKG1 | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as COSV100907092; called by muse, mutect2, varscan2
- RTL9 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1226725620; called by muse, mutect2
- SLC9C1 | c.2723A>G p.Y908C | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1560036304; called by muse, mutect2
- ZBTB21 | c.1165T>A p.C389S | Missense Mutation (SNP) | VAF 15/446 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1026612034; called by muse, mutect2
- ZPLD1 | c.1006G>A p.A336T (on ENST00000466937 / NM_001329788.1; = p.A352T on NM_175056.2) | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.52); catalogued as rs1030698681; called by muse, mutect2
- APP | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASH1L | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); called by muse, mutect2
- ATR | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- CAP2 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CCDC148 | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- CPOX | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 18/590 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXA2 | c.1042_1055del p.H348Afs*9 (on ENST00000377115 / NM_153675.3; = p.H354Afs*9 on NM_021784.5) | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- H6PD | c.1121A>G p.K374R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MFSD6L | c.554C>A p.A185D | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.038); called by mutect2, varscan2
- NLGN4X | c.2018C>T p.T673I | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); called by muse, mutect2
- OR52E8 | c.862G>C p.V288L | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2
- PGBD4 | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC5A3 | c.1808T>G p.V603G | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SPCS2 | c.288A>G p.I96M | Missense Mutation (SNP) | VAF 10/420 reads (2%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2
- TCF19 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); called by muse, mutect2
- VTI1A | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- XKR6 | c.1616C>A p.T539N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- XPO7 | c.1541A>G p.D514G | Missense Mutation (SNP) | VAF 30/377 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2
- ZNF350 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFT74 | c.1473A>G p.K491= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs1055614699; called by muse, mutect2
- ITPRID1 | c.2754G>A p.R918= | Silent (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- MARVELD3 | c.108C>T p.D36= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- PLXNA3 | c.3801G>A p.V1267= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- ASH1L | c.5828+4930T>C | Intron (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- DLGAP3 | c.*183G>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
- MIR525 | n.52G>C | RNA (SNP) | VAF 14/74 reads (19%) | called by muse, varscan2
- SYTL2 | c.1459+2615C>T | Intron (SNP) | VAF 9/193 reads (5%) | called by muse, mutect2
